Somatic mutation profile of tumor specimen TCGA-J4-A67M-01A (aliquot TCGA-J4-A67M-01A-11D-A30E-08) from TCGA case TCGA-J4-A67M, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 55.3 years (20,211 days).
Specimen TCGA-J4-A67M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a02a50f-5b6f-461b-98ed-5174866c10ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J4-A67M-10A (Blood Derived Normal), aliquot TCGA-J4-A67M-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6749638c-11ea-4ea0-9e0f-6f31303f41ea

The open-access MAF lists 35 somatic variants for this specimen: 25 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 20, Silent 10, Frame Shift Del 2, Nonsense Mutation 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB1 | c.2416G>A p.D806N | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.229); catalogued as COSV55951245; called by muse, mutect2, varscan2
- ADGRL3 | c.3619C>T p.R1207* (on ENST00000506720 / NM_001322402.2; = p.R1139* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 7/102 reads (7%) | catalogued as COSV72230574; called by muse, mutect2
- ALPG | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 20/251 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs568507509, COSV54964676; called by muse, mutect2
- CLEC1A | c.806T>C p.L269P | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59532074; called by muse, mutect2, varscan2
- CTNNAL1 | c.868A>G p.I290V | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV57702919; called by mutect2, varscan2
- DHX57 | c.2707C>T p.P903S | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); catalogued as COSV54885415; called by muse, mutect2, varscan2
- DNAH10 | c.11128C>T p.R3710W (on ENST00000409039; = p.R3649W on NM_207437.3) | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200977125, COSV101292234; called by muse, mutect2, varscan2
- DNAJB8 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 41/231 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs778186479, COSV59878117; called by muse, mutect2, varscan2
- EP300 | c.5490G>T p.R1830S | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54332694; called by muse, mutect2, varscan2
- EPB41L3 | c.2302G>A p.A768T | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.139); catalogued as rs558098862, COSV59453540, COSV59456315; called by muse, mutect2, varscan2
- FAN1 | c.2954A>G p.H985R | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.34); catalogued as rs764478646, COSV58728257; called by muse, mutect2, varscan2
- FMNL1 | c.485+1G>A p.X162_splice | Splice Site (SNP) | VAF 7/80 reads (9%) | catalogued as rs1278408574, COSV58956934; called by muse, mutect2
- GRIA1 | c.1852G>A p.V618I | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs760957944, COSV53603012; called by muse, mutect2, varscan2
- NCAM2 | c.1500T>A p.Y500* | Nonsense Mutation (SNP) | VAF 12/78 reads (15%) | catalogued as COSV53075255; called by muse, mutect2, varscan2
- NDUFA10 | c.178A>G p.I60V | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.178); catalogued as rs781189175, COSV53154266; called by muse, mutect2, varscan2
- OR4K15 | c.337C>T p.R113C (on ENST00000305051; = p.R89C on NM_001005486.1) | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs201446213, COSV59301399; called by muse, mutect2, varscan2
- PIGO | c.902A>G p.Y301C | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs771571749, COSV53053676; called by muse, mutect2, varscan2
- RUFY4 | c.1094C>T p.S365L | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs773995516, COSV60246305; called by muse, mutect2, varscan2
- SGIP1 | c.1304G>A p.G435E | Missense Mutation (SNP) | VAF 59/362 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV52768949; called by muse, mutect2, varscan2
- SYNE1 | c.2836G>T p.A946S (on ENST00000367255 / NM_182961.4; = p.A953S on NM_033071.3) | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); catalogued as COSV54981117; called by muse, mutect2, varscan2
- UPF2 | c.1394G>A p.R465Q | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.944); catalogued as rs774409157, COSV62660554; called by muse, mutect2
- ZEB2 | c.470A>G p.D157G | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as rs761041545, COSV57956824; called by muse, mutect2, varscan2
- ZNF721 | c.2279A>T p.E760V (on ENST00000338977; = p.E772V on NM_133474.4) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV59092486; called by muse, mutect2, varscan2
- ORC1 | c.2089_2090del p.L697Kfs*4 | Frame Shift Del (DEL) | VAF 9/91 reads (10%) | called by mutect2, pindel, varscan2
- ZNF28 | c.1421_1422del p.K474Sfs*9 | Frame Shift Del (DEL) | VAF 14/166 reads (8%) | called by mutect2, pindel
- CIAO2A | c.444A>G p.L148= | Silent (SNP) | VAF 16/130 reads (12%) | catalogued as COSV55537795, COSV55538422; called by muse, mutect2, varscan2
- HCN1 | c.2229G>A p.P743= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as COSV57510678; called by muse, mutect2, varscan2
- HMGCR | c.391T>C p.L131= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as COSV55315655; called by muse, mutect2, varscan2
- KCNF1 | c.534G>A p.S178= | Silent (SNP) | VAF 5/92 reads (5%) | catalogued as COSV54463470; called by muse, mutect2
- OR10J5 | c.147C>T p.I49= | Silent (SNP) | VAF 28/150 reads (19%) | catalogued as COSV58386070; called by muse, mutect2, varscan2
- PDIA4 | c.1803C>T p.F601= (on ENST00000286091 / NM_001371244.1; = p.F600= on NM_004911.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/98 reads (9%) | catalogued as rs374274813; called by muse, mutect2
- SAA2 | c.273G>A p.A91= | Silent (SNP) | VAF 21/110 reads (19%) | catalogued as rs200634677, COSV56777146; called by muse, mutect2, varscan2
- SLCO6A1 | c.969C>T p.V323= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as rs866381547, COSV65805356; called by muse, mutect2, varscan2
- SNAP29 | c.60C>T p.A20= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs1295614953, COSV53142653; called by muse, mutect2, varscan2
- UNC79 | c.1302G>A p.T434= (on ENST00000393151 / NM_001346218.2; = p.T257= on NM_020818.5) | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV56387929; called by muse, mutect2, varscan2
